Somatic mutation profile of tumor specimen BA2665D (aliquot aq-BA2665D) from BEATAML1.0 case 2006, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Myelodysplastic syndrome, unclassifiable; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.4 years (22,809 days).
Specimen BA2665D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8434823-b8a9-4a6d-a215-fa79645ec7a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2755D (Solid Tissue Normal), aliquot aq-BA2755D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/490784a9-b024-463a-9ec9-e162ebe44bea

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCTD19 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753673167, COSV58574088; called by muse, mutect2, varscan2
- PCDHA11 | c.2153C>T p.T718M | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.14); catalogued as rs781990448; called by muse, mutect2, varscan2
- RHOJ | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201823617; called by muse, mutect2, varscan2
- SNAP91 | c.2167G>T p.D723Y | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52118664; called by muse, mutect2
- TP53 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 92/162 reads (57%) | catalogued as CM103214, COSV52683572; called by muse, mutect2, varscan2
- BRCA1 | c.751A>G p.K251E | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- GRIN1 | c.1676A>T p.Q559L | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RAB11FIP4 | c.1746G>T p.Q582H | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC22A8 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HYDIN | c.7623C>T p.A2541= | Silent (SNP) | VAF 71/142 reads (50%) | catalogued as COSV59271121; called by muse, mutect2, varscan2
- SLC22A3 | c.708G>A p.S236= | Silent (SNP) | VAF 135/301 reads (45%) | catalogued as rs573086930, COSV51713112, COSV99279363; called by muse, mutect2, varscan2
- DFFB | c.241+1628T>G | Intron (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- MACROD2 | c.859+845G>A | Intron (SNP) | VAF 71/182 reads (39%) | called by muse, varscan2
